Gene-level copy-number profile of tumor specimen TCGA-3H-AB3K-01A from TCGA case TCGA-3H-AB3K, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 64.6 years (23,591 days).
Specimen TCGA-3H-AB3K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.65ab6f49-d2d2-458d-82a3-3798627c0221.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3H-AB3K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/030fa692-8889-4b43-b636-ddf25e986728

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 7,404; copy number 2: 51,357; copy number 3: 1,056.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3H-AB3K-01A-11D-A39Q-01): tumor purity 0.77, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:4,023,917–4,075,165, 3 genes: FTLP3, RPL21P2, AL356414.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,017. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
